Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A3F0, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A3F0-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

THYROID, TOTAL THYROIDECTOMY (18 GRAMS) -

- A. PAPILLARY THYROID CARCINOMA, ENCAPSULATED FOLLICULAR VARIANT (1.4 CM), RIGHT LOBE, CONFINED TO THYROID; NO CAPSULAR OR ANGIOLYMPHATIC INVASION.
- B. FOLLICULAR ADENOMA (2.0 CM), LEFT LOBE, WITH FOCAL ONCOCYTIC CHANGE.
- C. PATHOLOGIC STAGE: pT1bNx.
- D. NODULAR THYROID HYPERPLASIA AND MILD CHRONIC LYMPHOCYTIC THYROIDITIS.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE:	Total Thyroidectomy
TUMOR SITE:	Right Lobe
TUMOR FOCALITY:	Unifocal
TUMOR SIZE (largest nodule):	Greatest Dimension: 1.4 cm
HISTOLOGIC TYPE**:	Papillary carcinoma, encapsulated follicular variant
PRIMARY TUMOR (pT):	pT1b
REGIONAL LYMPH NODES (pN):	pNX

EXTRANODAL EXTENSION:	Not identified
DISTANT METASTASIS (pM):	Not applicable
EXTRATHYROIDAL EXTENSION:	Not identified
MARGINS:	Margins uninvolved by carcinoma
LYMPH-VASCULAR INVASION:	Not identified
ADDITIONAL PATHOLOGIC FINDINGS:	Adenoma Thyroiditis Other: nodular hyperplasia

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Thyroid nodule.
PROCEDURE: Not answered.
SPECIFIC CLINICAL QUESTION: Not answered.
OUTSIDE TISSUE DIAGNOSIS: Not answered.
PRIOR MALIGNANCY: Not answered.
CHEMORADIATION: Not answered.
ORGAN TRANSPLANT: Not answered.
IMMUNOSUPPRESSION: Not answered.
OTHER DISEASES: Not answered.

HIIPA Discrepancy		☒

ICA-0-3

Carcinoma, papillary, follicular variant 8340/3
Site: thyroid, NOS C73.9 11/4/11

Source: NCI Genomic Data Commons file 9c04c9b7-b064-4624-88c3-cf3173169e32 (TCGA-BJ-A3F0.76EF266D-8501-468F-9269-2ABA8D19CA53.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).